CCDI case PBCBFR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/26dd0945-e4ec-4019-b119-0c326ed9eb38

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Follicular carcinoma, minimally invasive: ICD-O-3 morphology code: 8335/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.5 years (5,285 days).

Biospecimens (3 samples)
- Sample 0DN83M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN83O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN83R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
